Surgical pathology report (de-identified scan), TCGA case TCGA-F2-A8YN, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site UNC, specimen TCGA-F2-A8YN-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

- A: Common bile duct, biopsy
- Benign bile duct
- No carcinoma identified

*ICD.O-3
Adenocarcinoma, duct NOS 8550.3
Site: Pancreas head C25.0
p 4/2/14*

- B: Pancreatic duct margin, biopsy
- Benign pancreatic duct
- No carcinoma identified

- C: Gallbladder, cholecystectomy
- Benign gallbladder with no significant pathologic abnormality
- No carcinoma identified

D: Pancreas, duodenum, distal stomach, and common bile duct,
pancreaticoduodenectomy

Tumor Histologic Type: invasive pancreatic ductal adenocarcinoma
(see comment)

Histologic grade: moderately differentiated

Tumor size: 4.8 cm

Tumor site: head of pancreas extending to involve duodenum

Microscopic tumor extension:

- Tumor invades duodenal wall and peripancreatic soft tissues

Lymph-vascular invasion: present

Perineural Invasion: not identified

Margins:

Uncinate process (retroperitoneal) margin: positive for
involvement by tumor (slide D6)

Peripancreatic soft tissues: <1 mm from the inked peripancreatic
soft tissue margin (slide D7)

Pancreatic resection margin: uninvolved by tumor, approximately
2.5 cm away

Bile duct margin: uninvolved by tumor, approximately 4.5 cm away

Proximal (gastric): negative, widely free

Distal (duodenal): negative, widely free

[page 2 of 5]
Lymph nodes:

Number of lymph nodes involved: 0

Number of lymph nodes examined: 13

Additional pathologic findings: mild acute and chronic pancreatitis with patchy autolysis

AJCC Pathologic TNM Stage: pT3 pN0

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

Grossly, a 4.8 cm tumor is identified that is evenly distributed between the duodenum and head of pancreas. While there are no available immunohistochemical stains to reliably distinguish a primary duodenal adenocarcinoma from a pancreatic ductal adenocarcinoma, the tumor morphology (glandular structures with abundant clear to pink apical cytoplasmic mucin) and the absence of a precursor lesion within the duodenal mucosa both favor a pancreatic primary.

Intraoperative Consult Diagnosis:

A frozen section consultation was requested by Dr. on _____ in _____

FSA1: Common bile duct, biopsy

- No tumor seen
- No atypical glandular mucinous epithelial proliferation identified
- Consistent with common bile duct with chronic inflammation

Drs. and on _____

FSB1: Pancreatic duct margin, biopsy

- No tumor seen

Drs. and on _____

Frozen Section Pathologist: _____, MD

Clinical History:

-year-old male with a mass in the third portion of the duodenum with a history of atypical glandular mucinous proliferation from previous duodenal biopsy.

[page 3 of 5]
Gross Description:

Received are four appropriately labeled containers. Specimens A and B are received fresh for frozen section.

Container A is received fresh for frozen section, and additionally labeled "common bile duct." It holds a 6 x 3 x 3 mm red/tan soft tissue fragment; block FSA1,

Container B holds a 5 x 5 x 3 mm red/tan soft tissue fragment; tissue is submitted in block FSB1,

Container C:

Previously opened or disrupted: yes, The gallbladder has been opened along its long axis.

Measurements: 7.8 x 4.2 x 1.2 cm

External surface: covered with a layer of smooth yellow fat

Luminal contents: none identified; the gallbladder was received opened

Stones present: none identified

Mucosa: pale, green and velvety

Wall thickness: 2 mm

Other comments: none

Block #: C1, cystic duct margin, en face and representative sections from the body and fundus

Tissue remains.

Container D is additionally labeled "pancreaticoduodenectomy."

Specimen fixation: formalin

Specimen type: standard Whipple

Organs received (Whipple Specimen): Stomach (2.0 cm in length, 2.5 cm in diameter); Head of pancreas (8.5 x 6.3 x 3.1 cm); Duodenum (28.5 cm in length x 6.0 cm in circumference); Common bile duct (4.5 cm in length x 0.6 cm in diameter)

Orientation: Short stitch on the pancreatic duct margin, long stitch on the common bile duct margin, and a blue stitch on the uncinate margin.

Inking: common bile duct=yellow, pancreatic neck margin=blue, uncinate margin=black, peripancreatic soft tissue=green.

[page 4 of 5]
Tumor location: duodenum and head of pancreas

Tumor dimensions: 4.8 x 4.5 x 4.0 cm

Gross appearance of tumor: In the duodenum, the tumor is ulcerated, tan and fibrous. In the pancreas, tumor is yellow/white, firm with ill-defined edges.

Extent of invasion:

Confined / non-confined to the pancreas: non-confined

Involvement of the ampulla: absent

Involvement of the duodenum: present

Involvement of the bile duct: absent

Involvement of adjacent vessels: absent

Spleen (if applicable): n/a

Gallbladder (if applicable): please see Specimen C

Stomach (if applicable): not involved by tumor

Surgical margins:

Pancreatic body: negative to 2.5 cm

Uncinate (Retroperitoneal): tumor is present on the black inked uncinate margin

Common Bile duct: negative to 4.5 cm

Proximal margin (stomach): widely negative

Distal margin (duodenum): widely negative

Peripancreatic soft tissues: The tumor abuts the green inked margin

Lymph nodes: Please see block summary

Other remarkable features: The uninvolved pancreas is yellow and lobulated with intervening fat.

[page 5 of 5]
Digital photograph taken: not taken

Tissue submitted for special investigation: Tissue submitted to
Tissue Procurement.

Block Summary:

- D1 - proximal mucosal margin, en face
- D2 - distal mucosal margin, en face
- D3 - common bile duct margin, en face
- D4-D5 - blue inked pancreatic body margin, bisected
- D6 - tumor with uncinate margin, perpendicular
- D7 - tumor with respect to inked peripancreatic soft tissue margin, perpendicular
- D8 - tumor with respect to common bile duct
- D9 - tumor, common bile duct and small bowel mucosa, bisected
- D10 - tumor with respect to ampulla
- D11 - tumor with respect to ampulla
- D12-D14 tumor with respect to small bowel
- D15 - one lymph node candidate, bisected
- D16-D19 multiple lymph node candidates each
- D20 - one lymph node candidate, trisected
- D21 - one lymph node candidate, bisected

Source: NCI Genomic Data Commons file bc7a16f1-9fd8-43f4-bc19-b37d25ec3783 (TCGA-F2-A8YN.1929E429-7614-4B96-A4DA-D4E109F704B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).